Somatic mutation profile of tumor specimen TCGA-KB-A93G-01A (aliquot TCGA-KB-A93G-01A-11D-A397-08) from TCGA case TCGA-KB-A93G, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G1; Age at diagnosis: 68.2 years (24,924 days).
Specimen TCGA-KB-A93G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9cc4e143-8d85-436a-b198-89bb0f0e0452.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KB-A93G-10A (Blood Derived Normal), aliquot TCGA-KB-A93G-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e928a90-602e-4cdc-ac1a-c669f8df579c

The open-access MAF lists 93 somatic variants for this specimen: 68 protein-altering or splice-affecting, 20 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 20, Nonsense Mutation 7, Intron 2, Frame Shift Del 2, Splice Site 1, RNA 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 20/132 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACADM | c.1007G>A p.S336N | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as rs794727013, CM125174, COSV100897743; ClinVar: uncertain significance; called by muse, mutect2
- ADGRB3 | c.1035C>A p.H345Q | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV101001633, COSV65392623; called by muse, mutect2
- ANO5 | c.739T>A p.S247T | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV100202115, COSV61082087; called by muse, mutect2, varscan2
- APC | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99969628; called by muse, mutect2, varscan2
- APCDD1L | c.697C>A p.H233N | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV100954056, COSV64487960; called by muse, mutect2
- ASTN1 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1397720198, COSV56076060; called by muse, mutect2
- AXIN2 | c.490C>G p.Q164E | Missense Mutation (SNP) | VAF 6/147 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as COSV100196877; called by muse, mutect2
- CADM1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); catalogued as COSV100523245; called by muse, mutect2, varscan2
- CASZ1 | c.3454G>A p.A1152T | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs763703517, COSV100681821; called by muse, mutect2, varscan2
- CD163 | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs747400028, COSV63136046, COSV99051821; called by muse, mutect2
- CD1C | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 7/170 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV100939438; called by muse, mutect2
- CEP95 | c.1399del p.R467Gfs*26 | Frame Shift Del (DEL) | VAF 5/45 reads (11%) | catalogued as rs1555679804; called by mutect2, varscan2
- CFAP206 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs371084143, COSV99739571; called by muse, mutect2
- CHGB | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as COSV100973058; called by muse, mutect2
- COG8 | c.1516C>T p.L506F | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV99846578; called by muse, mutect2
- CSMD1 | c.7298G>T p.C2433F (on ENST00000520002; = p.C2432F on NM_033225.6) | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100152696; called by muse, mutect2, varscan2
- CSTF1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 37/347 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs751350281, COSV99410314; called by muse, mutect2, varscan2
- DENND3 | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs751024080, COSV99370902; called by muse, mutect2, varscan2
- DLD | c.1236+1G>A p.X412_splice | Splice Site (SNP) | VAF 12/142 reads (8%) | catalogued as COSV99227432; called by muse, mutect2
- DNAH2 | c.7091G>A p.R2364Q | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as rs761361398, COSV101209545; called by muse, mutect2
- DNAH5 | c.9962G>A p.R3321Q | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs750927507, COSV54205756; called by muse, mutect2, varscan2
- DNAH5 | c.2791G>T p.A931S | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99453063; called by muse, mutect2, varscan2
- DNAI1 | c.1615C>T p.H539Y | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99647085; called by muse, mutect2
- IGHV3-15 | c.125C>A p.A42E | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); catalogued as rs528746234; called by muse, mutect2
- KRT72 | c.1466G>T p.G489V | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.005); catalogued as COSV99537444; called by muse, mutect2, varscan2
- LIN7B | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs750351904, COSV99674574; called by muse, mutect2, varscan2
- LTBP1 | c.3088C>T p.R1030* (on ENST00000404816 / NM_206943.4; = p.R704* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 6/136 reads (4%) | catalogued as COSV100617852; called by muse, mutect2
- MAGED1 | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs782675141, COSV58515023; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MARK4 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 6/141 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs1169062430, COSV53465323; called by muse, mutect2
- MC3R | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99710814; called by muse, mutect2
- MNDA | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV100933423; called by muse, mutect2
- MROH5 | c.1416G>T p.Q472H | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV101436106, COSV71302812; called by muse, mutect2, varscan2
- MTRF1L | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 30/321 reads (9%) | catalogued as COSV100922494, COSV100922502; called by muse, mutect2
- MUC16 | c.34050G>T p.W11350C | Missense Mutation (SNP) | VAF 29/296 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.937); catalogued as rs984889522, COSV101201113; called by muse, mutect2, varscan2
- NAT10 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99140402; called by muse, mutect2
- NCBP1 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as COSV100912659; called by muse, mutect2
- NOVA1 | c.724C>A p.Q242K | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.828); catalogued as rs1281233261, COSV99948480; called by muse, mutect2, varscan2
- NSD3 | c.1679C>T p.S560L | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as rs1420471815, COSV57622651; called by muse, mutect2, varscan2
- OR14A16 | c.498C>A p.Y166* | Nonsense Mutation (SNP) | VAF 12/156 reads (8%) | catalogued as COSV100713847; called by muse, mutect2
- OR2L3 | c.96C>A p.F32L | Missense Mutation (SNP) | VAF 15/404 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63456738; called by muse, mutect2
- PCDHB5 | c.2159C>T p.P720L | Missense Mutation (SNP) | VAF 58/333 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs782775493, COSV99169364, COSV99169424; called by muse, mutect2, varscan2
- PITPNC1 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV55445457; called by muse, mutect2
- PPP6R1 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV101337009; called by muse, mutect2
- PSMD2 | c.1431G>A p.M477I | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT tolerated (0.84); PolyPhen benign (0.382); catalogued as rs1344991750, COSV100031968; called by muse, mutect2
- PTGER4 | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100201718; called by muse, mutect2, varscan2
- RAP1GAP | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); catalogued as rs1438026416, COSV99265736; called by muse, mutect2, varscan2
- RPL28 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as rs755535252, COSV100689467, COSV59805070; called by muse, mutect2, varscan2
- RYR2 | c.5688G>C p.M1896I | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.218); catalogued as COSV100768940, COSV100772267; called by muse, mutect2
- SCUBE1 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs367576701; called by muse, mutect2, varscan2
- SLC1A5 | c.818T>A p.I273N | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV101314814; called by muse, mutect2
- SOCS6 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs753212305; called by muse, mutect2, varscan2
- SPICE1 | c.1256T>G p.L419R | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99871695; called by muse, mutect2
- SPTA1 | c.5509G>T p.E1837* | Nonsense Mutation (SNP) | VAF 15/202 reads (7%) | catalogued as COSV100935429, COSV63758216; called by muse, mutect2
- STXBP1 | c.257C>G p.S86C | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs1182223011, COSV100964627; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE1 | c.14998C>G p.Q5000E (on ENST00000367255 / NM_182961.4; = p.Q4929E on NM_033071.3) | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.057); catalogued as COSV99575460; called by muse, mutect2, varscan2
- TPO | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs150812908; ClinVar: uncertain significance; called by muse, mutect2
- TRAF1 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1380027488, COSV100875199; called by muse, mutect2, varscan2
- TRPM8 | c.818T>G p.V273G | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100224441; called by muse, mutect2
- UHRF1BP1L | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99692024, COSV99692125; called by muse, mutect2, varscan2
- WASHC4 | c.1666C>T p.R556* | Nonsense Mutation (SNP) | VAF 20/306 reads (7%) | catalogued as rs1439500852, COSV59889019; called by muse, mutect2
- WBP1 | c.617G>C p.R206P | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99270728; called by muse, mutect2
- ZFYVE26 | c.7094G>C p.G2365A | Missense Mutation (SNP) | VAF 19/263 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100720682; called by muse, mutect2
- ZNF43 | c.606C>A p.C202* | Nonsense Mutation (SNP) | VAF 7/123 reads (6%) | catalogued as COSV100731927; called by muse, mutect2
- ZYG11B | c.2023C>T p.Q675* | Nonsense Mutation (SNP) | VAF 20/157 reads (13%) | catalogued as COSV53754552; called by muse, mutect2, varscan2
- DNAH5 | c.3844G>T p.A1282S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2
- IGHV3-49 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 18/299 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- NANS | c.636del p.I212Mfs*10 | Frame Shift Del (DEL) | VAF 33/255 reads (13%) | called by mutect2, pindel, varscan2
- BCL7A | c.528G>A p.S176= | Silent (SNP) | VAF 11/186 reads (6%) | catalogued as rs1296490434; called by muse, mutect2
- CD163 | c.2283C>A p.G761= | Silent (SNP) | VAF 27/260 reads (10%) | catalogued as COSV100776073; called by muse, mutect2
- DGKK | c.399G>A p.S133= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as rs782553959, COSV101053170; called by muse, mutect2, varscan2
- DSCAM | c.1434C>T p.D478= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as rs759939882, COSV101261409, COSV68020523; called by muse, mutect2
- GABRR1 | c.450C>T p.V150= | Silent (SNP) | VAF 47/570 reads (8%) | catalogued as COSV101034075, COSV65619547; called by muse, mutect2
- GCOM1 | c.897C>T p.I299= | Silent (SNP) | VAF 9/124 reads (7%) | catalogued as rs771663802, COSV99985232; called by muse, mutect2
- GDPGP1 | c.891G>A p.P297= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as rs751349552; called by muse, mutect2, varscan2
- KRTAP19-3 | c.78C>T p.G26= | Silent (SNP) | VAF 30/274 reads (11%) | catalogued as COSV100477629; called by muse, mutect2
- LILRA2 | c.261C>T p.I87= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV52196565; called by muse, mutect2, varscan2
- NOL4L | c.93C>T p.L31= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV100394025; called by muse, mutect2
- OR5H1 | c.111C>A p.I37= | Silent (SNP) | VAF 19/509 reads (4%) | called by muse, mutect2
- PRR23B | c.714C>T p.C238= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs1208919122, COSV61494007, COSV61495271; called by muse, mutect2, varscan2
- RSPH6A | c.1560C>T p.Y520= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs746281353, COSV99680064; called by muse, mutect2, varscan2
- RTL10 | c.33T>A p.P11= | Silent (SNP) | VAF 16/178 reads (9%) | catalogued as COSV100144280; called by muse, mutect2
- SCG3 | c.114A>G p.A38= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as COSV99591147; called by muse, mutect2
- SCRIB | c.2604C>T p.S868= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs767046372, COSV57586212; called by muse, mutect2
- SERPINI2 | c.195A>T p.G65= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as COSV99248297; called by muse, mutect2
- SIN3B | c.2544C>T p.Y848= | Silent (SNP) | VAF 16/172 reads (9%) | catalogued as rs781213449, COSV99931986; called by muse, mutect2
- SLC7A9 | c.843C>T p.T281= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs1279911121, COSV50090818; called by muse, mutect2, varscan2
- UBR4 | c.12291G>A p.L4097= | Silent (SNP) | VAF 13/273 reads (5%) | catalogued as rs1279650297, COSV100921567; called by muse, mutect2
- C7orf66 | n.190G>T | RNA (SNP) | VAF 8/177 reads (5%) | called by muse, mutect2
- MAGEC3 | c.1124-185C>G | Intron (SNP) | VAF 17/85 reads (20%) | catalogued as COSV100025457, COSV100025962; called by muse, mutect2, varscan2
- SCRIB | c.4695+164G>A | Intron (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100253776, COSV100253989; called by muse, mutect2
- SPACA6 | chr19:51692642 G>C | 5'Flank (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- UPF2 | c.*250C>G | 3'UTR (SNP) | VAF 7/65 reads (11%) | catalogued as COSV100707410; called by mutect2, varscan2
